Somatic mutation profile of tumor specimen TCGA-69-7763-01A (aliquot TCGA-69-7763-01A-11D-2167-08) from TCGA case TCGA-69-7763, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.3 years (25,316 days).
Specimen TCGA-69-7763-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dfec7687-58d5-4ed0-951e-d75ac11b52fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-69-7763-10A (Blood Derived Normal), aliquot TCGA-69-7763-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc5acadd-ea8f-4e82-ab61-fb990945d07b

The open-access MAF lists 77 somatic variants for this specimen: 52 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 22, Nonsense Mutation 6, 3'UTR 2, Splice Region 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.179dup p.Y60* | Nonsense Mutation (INS) | VAF 11/41 reads (27%) | catalogued as rs876661012, CI055775, COSV100479367; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADCY4 | c.1438C>T p.R480C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs779542530, COSV100156645, COSV60257556; called by muse, mutect2, varscan2
- ALDH1L1 | c.2239G>A p.G747R | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746651860, COSV56414277; called by muse, mutect2, varscan2
- ATP7B | c.4163C>T p.A1388V | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs371458882; ClinVar: uncertain significance; called by mutect2, varscan2
- ATP8A2 | c.2303C>A p.T768N | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54976080, COSV99679352; called by muse, mutect2
- ATXN1 | c.473C>A p.A158E | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV55230757; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4819G>A p.D1607N | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.981); catalogued as COSV63247341; called by muse, mutect2, varscan2
- C1orf127 | c.1985C>T p.A662V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1322098857, COSV65438902; called by muse, mutect2, varscan2
- CENPJ | c.60G>C p.W20C | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV67884219; called by muse, mutect2, varscan2
- CLCN4 | c.1957G>T p.E653* | Nonsense Mutation (SNP) | VAF 4/10 reads (40%) | catalogued as COSV101073973; called by muse, mutect2
- CLUL1 | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs550299496, COSV58113441; called by muse, mutect2, varscan2
- CSRNP2 | c.1417T>G p.S473A | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV50399882; called by muse, mutect2, varscan2
- CXCR6 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as rs141955108; called by muse, mutect2, varscan2
- DHX8 | c.394A>T p.T132S | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.74); PolyPhen benign (0.01); catalogued as COSV52256562; called by muse, mutect2, varscan2
- DNAH10 | c.11117G>A p.R3706Q (on ENST00000409039; = p.R3645Q on NM_207437.3) | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1282427153, COSV68989032; called by muse, mutect2, varscan2
- ECD | c.1268T>C p.L423P | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200978167, COSV65901249; called by muse, mutect2, varscan2
- FAT4 | c.9997G>T p.G3333W | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58708045; called by muse, mutect2, varscan2
- FLI1 | c.250A>G p.S84G | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.843); catalogued as COSV55647717; called by mutect2, varscan2
- FREM1 | c.1187G>T p.R396M | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV63087191, COSV63087597; called by muse, mutect2, varscan2
- GLRB | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV52422365; called by muse, mutect2, varscan2
- GPATCH8 | c.2540G>T p.S847I | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV59198302; called by muse, mutect2, varscan2
- GPR45 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs200554082; called by muse, mutect2, varscan2
- IL18RAP | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99962282; called by muse, mutect2
- INPPL1 | c.3718G>T p.G1240W | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53359248; called by muse, mutect2, varscan2
- KDR | c.591G>T p.M197I | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99818408; called by muse, mutect2
- KDR | c.590T>A p.M197K | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.094); catalogued as COSV99818413; called by muse, mutect2
- LRCH3 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.828); catalogued as rs777850185, COSV54086257; called by muse, varscan2
- LRP1B | c.7684C>A p.R2562S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.298); catalogued as COSV67194823, COSV67273073; called by muse, varscan2
- MYH7 | c.258A>T p.K86N | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV62523608; called by muse, mutect2, varscan2
- OPN5 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.057); catalogued as rs376934583; called by muse, mutect2, varscan2
- OXA1L | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.673); catalogued as rs377716019; called by muse, mutect2, varscan2
- PBX3 | c.1122G>A p.Q374= | Splice Region (SNP) | VAF 4/29 reads (14%) | catalogued as COSV60735863; called by muse, mutect2, varscan2
- PDE3B | c.839G>A p.S280N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.3); catalogued as COSV56390472; called by muse, mutect2, varscan2
- PI4K2A | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV65702265; called by muse, mutect2, varscan2
- PPP1R3A | c.618G>T p.E206D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV52892829; called by muse, mutect2, varscan2
- RYR1 | c.5720A>G p.E1907G | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV100616498, COSV62110319; called by muse, mutect2, varscan2
- SACS | c.8662G>A p.A2888T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV66546654; called by muse, mutect2, varscan2
- SLITRK1 | c.863C>A p.T288N | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.379); catalogued as rs370157685, COSV100999763, COSV65677515; called by muse, mutect2, varscan2
- SRD5A2 | c.5A>T p.Q2L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV51873642; called by muse, mutect2
- TLR4 | c.1585C>A p.H529N (on ENST00000355622 / NM_138554.5; = p.H489N on NM_003266.4) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.027); catalogued as COSV100842831; called by muse, mutect2, varscan2
- UNC5B | c.1510G>T p.G504W | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58981236; called by muse, mutect2, varscan2
- USP9X | c.6265G>T p.A2089S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs1284393294, COSV61074973; called by muse, mutect2, varscan2
- VEGFA | c.245G>T p.R82L (on ENST00000523873 / NM_001171623.1; = p.R262L on NM_003376.6) | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV57879855; called by muse, mutect2, varscan2
- ZBED8 | c.203A>T p.H68L | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.451); catalogued as COSV68825039; called by muse, mutect2, varscan2
- ZBED9 | c.2009A>C p.K670T | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.813); catalogued as COSV71729767; called by muse, mutect2, varscan2
- ZFP82 | c.1027T>C p.C343R | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1262337043, COSV67566727; called by muse, mutect2
- ZMYND8 | c.1957C>G p.P653A (on ENST00000311275 / NM_001363741.2; = p.P673A on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as COSV53696077; called by muse, mutect2, varscan2
- ZNF613 | c.590C>A p.T197N (on ENST00000293471 / NM_001031721.4; = p.T161N on NM_024840.4) | Missense Mutation (SNP) | VAF 56/278 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV53273921; called by muse, mutect2, varscan2
- ZNF619 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 17/52 reads (33%) | catalogued as COSV59031269; called by muse, mutect2, varscan2
- ZNF91 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV56092784; called by muse, mutect2, varscan2
- MARK4 | c.1535dup p.Y512* | Nonsense Mutation (INS) | VAF 10/86 reads (12%) | called by mutect2, pindel, varscan2
- MGA | c.2752_2758del p.I918Hfs*13 | Frame Shift Del (DEL) | VAF 15/102 reads (15%) | called by mutect2, pindel, varscan2
- AC004922.1 | c.1110C>T p.S370= | Silent (SNP) | VAF 22/186 reads (12%) | catalogued as rs144704984; called by muse, varscan2
- ADAMTSL2 | c.600G>T p.L200= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV100619011; called by muse, mutect2, varscan2
- ANKFN1 | c.219G>A p.T73= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs370848906, COSV59447743; called by muse, mutect2
- ATOH1 | c.447C>A p.S149= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100024557; called by muse, mutect2, varscan2
- ELP2 | c.1212C>T p.I404= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV60854377; called by muse, mutect2, varscan2
- EYS | c.204T>A p.T68= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as COSV100676720, COSV60999762; called by muse, mutect2
- KCNC1 | c.114G>A p.A38= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as rs200677353; called by muse, mutect2
- KCNU1 | c.534C>A p.T178= | Silent (SNP) | VAF 3/13 reads (23%) | catalogued as COSV101299397; called by muse, mutect2
- LRP2 | c.3270C>T p.N1090= | Silent (SNP) | VAF 35/187 reads (19%) | catalogued as rs373632128, COSV55573528; called by muse, mutect2, varscan2
- PCDHB15 | c.2049C>T p.A683= | Silent (SNP) | VAF 49/189 reads (26%) | catalogued as COSV51412759, COSV99178849; called by muse, mutect2, varscan2
- PRAM1 | c.72C>G p.A24= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV55317068; called by muse, mutect2
- RYK | c.1380C>T p.A460= (on ENST00000620660 / NM_001005861.2; = p.A457= on NM_002958.4) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99938537; called by muse, varscan2
- SCARF1 | c.1731G>A p.P577= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as rs768750101, COSV53957692; called by muse, mutect2, varscan2
- SIGLEC12 | c.1776C>T p.N592= (on ENST00000291707 / NM_053003.4; = p.N474= on NM_033329.2) | Silent (SNP) | VAF 38/178 reads (21%) | catalogued as COSV52463858, COSV52464838; called by muse, mutect2, varscan2
- SPRY3 | c.414G>C p.G138= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV57141933, COSV57144345; called by muse, mutect2, varscan2
- STYXL1 | c.582C>T p.S194= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV50392377; called by muse, mutect2, varscan2
- SYNE1 | c.17446C>T p.L5816= (on ENST00000367255 / NM_182961.4; = p.L5745= on NM_033071.3) | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs1298836176, COSV55097529; called by muse, mutect2, varscan2
- TLE4 | c.996G>T p.A332= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV54641127; called by muse, mutect2, varscan2
- ZBTB9 | c.1305A>T p.G435= | Silent (SNP) | VAF 16/130 reads (12%) | catalogued as COSV67702404; called by muse, mutect2, varscan2
- ZNF285 | c.789C>T p.D263= | Silent (SNP) | VAF 35/129 reads (27%) | catalogued as COSV58411161; called by muse, mutect2, varscan2
- ZNF354B | c.1029A>G p.G343= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV59367410; called by muse, mutect2, varscan2
- ZNF488 | c.564C>T p.A188= | Silent (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- ATP2B1 | c.3351+510C>T | Intron (SNP) | VAF 19/117 reads (16%) | catalogued as COSV53811996; called by muse, mutect2, varscan2
- MAK | c.*1G>A | 3'UTR (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100504588; called by muse, mutect2, varscan2
- TMEM107 | c.*620C>T | 3'UTR (SNP) | VAF 6/41 reads (15%) | catalogued as rs374740618; called by mutect2, varscan2
